Somatic mutation profile of tumor specimen TCGA-86-8278-01A (aliquot TCGA-86-8278-01A-11D-2284-08) from TCGA case TCGA-86-8278, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.3 years (23,117 days).
Specimen TCGA-86-8278-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f719432-ed9c-4945-826b-e1a3a51eb239.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8278-10A (Blood Derived Normal), aliquot TCGA-86-8278-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc2f5320-ada0-44f6-b9d3-dea5d372ad85

The open-access MAF lists 101 somatic variants for this specimen: 78 protein-altering or splice-affecting, 19 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 19, Nonsense Mutation 9, Splice Site 3, RNA 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4874G>A p.R1625H | Missense Mutation (SNP) | VAF 30/100 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57431794, COSV57438402; called by muse, mutect2, varscan2
- ABCB10 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV104419269, COSV60621933; called by muse, mutect2
- ACTB | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100079927, COSV59322102; called by muse, mutect2
- AHNAK | c.8434G>A p.E2812K | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs936023498, COSV99949419; called by muse, mutect2
- AK7 | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99967523; called by muse, mutect2
- AP3M1 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100786762; called by muse, mutect2, varscan2
- ARID1A | c.2132C>G p.S711* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV61376007; called by muse, mutect2, varscan2
- ARID1B | c.4695G>C p.M1565I | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99271126, COSV99271666; called by muse, mutect2
- C12orf40 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100210713; called by muse, mutect2, varscan2
- CALB1 | c.17T>A p.L6Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99618542; called by muse, mutect2, varscan2
- CARD6 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV99621247, COSV99621277; called by muse, mutect2, varscan2
- CBLN4 | c.384A>C p.K128N | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99290722; called by muse, mutect2, varscan2
- CFHR5 | c.1558C>T p.Q520* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99888675; called by muse, mutect2
- CHRNB4 | c.762C>G p.F254L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99929587; called by muse, mutect2
- COL1A2 | c.324+1G>A p.X108_splice | Splice Site (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99800952; called by muse, mutect2, varscan2
- CRY2 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV101314616; called by muse, mutect2, varscan2
- CT55 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV99358971; called by muse, mutect2
- CUL1 | c.501G>C p.W167C | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296912; called by muse, mutect2, varscan2
- CUL9 | c.2776G>C p.E926Q | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as COSV99336004; called by muse, mutect2
- DDX58 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV100008595; called by muse, mutect2
- DGCR8 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100708160; called by muse, mutect2, varscan2
- DSCAML1 | c.607G>A p.V203I (on ENST00000321322; = p.V143I on NM_020693.4) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs554359582, COSV100357110, COSV58396444; called by muse, mutect2, varscan2
- EPX | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs573827983, COSV56595010; called by muse, mutect2, varscan2
- FAM3B | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV100783771; called by muse, mutect2, varscan2
- FLG | c.9832C>T p.H3278Y | Missense Mutation (SNP) | VAF 69/595 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1444730867, COSV100912095; called by muse, mutect2, varscan2
- GFAP | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs267607507, CM083519, COSV53649572, COSV99493614; called by muse, mutect2
- H1-5 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1245449679, COSV100137825, COSV100138069; called by muse, mutect2
- H2AC16 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs778934233, COSV100511411, COSV58899804; called by muse, mutect2
- HERC2 | c.10594C>G p.Q3532E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV99876571; called by muse, mutect2, varscan2
- HLTF | c.189G>C p.L63F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV100027111; called by muse, mutect2, varscan2
- HS3ST5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100451339; called by muse, mutect2, varscan2
- HYDIN | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865029; called by muse, mutect2
- KIAA0895 | c.108+1G>A p.X36_splice | Splice Site (SNP) | VAF 14/56 reads (25%) | catalogued as rs368071868, COSV99732798; called by muse, mutect2, varscan2
- KMT2A | c.1399C>G p.Q467E | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV100629744; called by muse, mutect2
- KRT6B | c.666G>C p.R222S | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV99360969; called by muse, mutect2
- LARP4 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 39/156 reads (25%) | catalogued as rs1565769829, COSV99529627; called by muse, mutect2, varscan2
- MAP4K3 | c.1394C>G p.S465* | Nonsense Mutation (SNP) | VAF 10/137 reads (7%) | catalogued as COSV99811054; called by muse, mutect2
- MKS1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100439615, COSV58303587; called by muse, mutect2
- MTG2 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778892688, COSV100895200; called by muse, mutect2
- NBAS | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99871479; called by muse, mutect2
- NOL4 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV99307867, COSV99308211; called by mutect2, varscan2
- OR1M1 | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.129); catalogued as rs770163695, COSV101447594; called by muse, mutect2, varscan2
- OVCA2 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1416448993, COSV99559644; called by muse, varscan2
- PLEC | c.7739A>G p.H2580R (on ENST00000322810 / NM_201380.4; = p.H2470R on NM_000445.5) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV100518555; called by muse, mutect2, varscan2
- PLXNA2 | c.4968G>C p.K1656N | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885847; called by muse, mutect2, varscan2
- PRAG1 | c.2310C>A p.C770* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100422767; called by muse, mutect2
- PRKCQ | c.1496G>C p.G499A | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99577760; called by muse, mutect2, varscan2
- RAPH1 | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.037); catalogued as COSV100051918; called by muse, mutect2, varscan2
- RNF32 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100311598; called by muse, mutect2
- RTF1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV101048187; called by muse, mutect2
- SAGE1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs781934045, COSV61011957, COSV61017693; called by muse, mutect2
- SALL1 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99180799; called by muse, mutect2, varscan2
- SALL4 | c.1445C>G p.S482C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1325164721, COSV53851950, COSV53853873, COSV99409810; called by muse, mutect2
- SERPINB5 | c.736-1G>C p.X246_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | catalogued as COSV101237695; called by muse, mutect2
- SEZ6 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1387863646, COSV100253508; called by muse, mutect2
- SLC12A4 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as COSV100312193, COSV57935029; called by muse, mutect2, varscan2
- SLC25A35 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99873926; called by muse, mutect2, varscan2
- SLC8A1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100247333; called by muse, mutect2
- SMAD2 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50992809; called by muse, mutect2, varscan2
- SOS2 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99366749; called by muse, mutect2, varscan2
- SP100 | c.2191C>G p.P731A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.344); catalogued as COSV100414423; called by muse, mutect2
- SPIDR | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.392); catalogued as COSV99854405, COSV99855991; called by muse, mutect2
- SPINT1 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV100689194; called by muse, mutect2, varscan2
- SSH3 | c.1627C>T p.L543F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs533168695, COSV100354783; called by muse, mutect2, varscan2
- SUGP2 | c.2346G>T p.M782I | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100432290; called by muse, mutect2, varscan2
- SVIL | c.4490C>T p.S1497L (on ENST00000355867 / NM_021738.3; = p.S1071L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV100881521; called by muse, mutect2, varscan2
- TBC1D14 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV101299037; called by muse, mutect2
- VPS13B | c.6036G>C p.Q2012H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100663445; called by muse, mutect2, varscan2
- XIRP2 | c.262G>A p.E88K (on ENST00000628543; = p.E263K on NM_152381.6) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV99746924; called by muse, mutect2, varscan2
- ZBTB3 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs894838534, COSV67360784, COSV67361584; called by muse, mutect2
- ZNF267 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV100339925, COSV56250468; called by muse, mutect2
- ZNF318 | c.1146G>C p.L382F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100546486; called by muse, mutect2
- ZNF334 | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV61619761; called by muse, mutect2, varscan2
- ZNF366 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); catalogued as COSV100574453; called by muse, mutect2, varscan2
- ZNF611 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV100160576; called by muse, mutect2
- ZSCAN22 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1219522681, COSV61639298; called by muse, mutect2, varscan2
- ASH1L | c.2135G>C p.R712T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- KIAA0319L | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.231); called by muse, mutect2
- ADAMTS15 | c.1335C>T p.S445= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100143760; called by muse, mutect2
- CDK5RAP2 | c.2343C>T p.F781= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100575721; called by muse, mutect2, varscan2
- EPB41L2 | c.1746C>T p.V582= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV100441354; called by muse, mutect2, varscan2
- FADS1 | c.672C>T p.L224= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99952524; called by muse, mutect2, varscan2
- FCN3 | c.741G>A p.V247= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99585121, COSV99585514; called by muse, mutect2
- GAREM1 | c.1116C>G p.L372= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV99331320; called by muse, mutect2, varscan2
- GTPBP4 | c.834C>G p.L278= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV100672917; called by muse, mutect2, varscan2
- ITPR3 | c.2805C>G p.V935= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100968074; called by muse, mutect2
- KLK9 | c.522C>G p.L174= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV51594777; called by muse, mutect2
- KRT73 | c.921T>C p.R307= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs1565629565, COSV99988833; called by muse, mutect2, varscan2
- MRGPRD | c.711G>A p.L237= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1343687238, COSV100483085; called by muse, mutect2, varscan2
- NF1 | c.6387C>T p.I2129= (on ENST00000358273 / NM_001042492.3; = p.I2108= on NM_000267.3) | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs786203078, COSV100648174; ClinVar: likely benign; called by muse, mutect2
- PCDHA7 | c.2004G>A p.S668= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs1435398883, COSV100971000; called by muse, mutect2, varscan2
- RBM19 | c.885C>T p.T295= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1221320304, COSV99926756; called by muse, mutect2, varscan2
- SEZ6L | c.1173G>C p.L391= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99962841; called by muse, mutect2, varscan2
- STXBP1 | c.228C>T p.L76= | Silent (SNP) | VAF 11/146 reads (8%) | catalogued as COSV100964632; called by muse, mutect2
- SVIL | c.1185A>T p.A395= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100881522; called by muse, mutect2, varscan2
- TLN2 | c.4720C>T p.L1574= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV100169934; called by muse, mutect2
- UBXN4 | c.609A>G p.T203= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV55633575; called by muse, varscan2
- CLLU1 | n.882C>G | RNA (SNP) | VAF 5/31 reads (16%) | catalogued as COSV65903063; called by muse, mutect2, varscan2
- MIR633 | n.54G>A | RNA (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-5176C>T | Intron (SNP) | VAF 12/113 reads (11%) | catalogued as COSV100335294; called by muse, mutect2, varscan2
- RPL23A | c.387-123C>G | Intron (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99411874; called by muse, mutect2, varscan2
